Somatic mutation profile of tumor specimen TCGA-J4-A67R-01A (aliquot TCGA-J4-A67R-01A-21D-A30E-08) from TCGA case TCGA-J4-A67R, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.2 years (23,807 days).
Specimen TCGA-J4-A67R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9496694a-f089-4551-a5a1-f29f58f1c032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A67R-10A (Blood Derived Normal), aliquot TCGA-J4-A67R-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53162127-4bac-4f32-ba4c-2c38855f7df2

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 6, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXO42 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV65044457; called by muse, mutect2
- FLT4 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs907068772, COSV56098172; called by muse, mutect2
- HCN1 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV57493557; called by muse, mutect2, varscan2
- NOS2 | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV58221620; called by muse, mutect2, varscan2
- PDHA2 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | catalogued as rs755333932, COSV54777202; called by muse, mutect2
- TNK1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs1488980270, COSV61169896; called by muse, mutect2
- ZNF789 | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV58873723; called by muse, mutect2, varscan2
- CD1D | c.306C>T p.F102= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as rs1333726776, COSV63808373; called by muse, mutect2
- FAM124A | c.411C>T p.H137= (on ENST00000322475 / NM_001242312.2; = p.H173= on NM_145019.4) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs757521370, COSV54474329; called by muse, mutect2
- IGHA1 | c.819C>T p.R273= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as rs778291607; called by muse, mutect2
- OR5AU1 | c.876G>A p.L292= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as COSV58615247; called by muse, mutect2, varscan2
- POTEE | c.495C>T p.D165= | Silent (SNP) | VAF 26/538 reads (5%) | catalogued as rs779199454, COSV58224170; called by muse, mutect2
- TUBGCP6 | c.189A>G p.K63= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as COSV50536495; called by muse, mutect2
